Somatic mutation profile of tumor specimen BA2233D (aliquot aq-BA2233D) from BEATAML1.0 case 2316, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.1 years (26,331 days).
Specimen BA2233D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75d6e4d9-2b79-4ed0-a982-96c8829ec9b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2077D (Solid Tissue Normal), aliquot aq-BA2077D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2378f0c2-55d1-46a2-ad53-090b4abb8fc9

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 26/71 reads (37%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, varscan2
- CYP2A13 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.857); catalogued as rs566665410, COSV100386665; called by muse, varscan2
- DHX38 | c.1126C>A p.R376S | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.115); called by muse, mutect2
- FRMPD3 | c.5018C>A p.A1673D | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MMP11 | c.848C>A p.A283E | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- ZNF157 | c.958C>A p.H320N | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXL18 | c.1086G>T p.L362= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV101212114; called by muse, mutect2
